Gene-level copy-number profile of tumor specimen TCGA-YU-A94L-01A from TCGA case TCGA-YU-A94L, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 23.4 years (8,550 days).
Specimen TCGA-YU-A94L-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ec4560d0-ec33-4a89-ada6-6f4427671f4a.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator TCGA-YU-A94L-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,715 have no estimate.
https://portal.gdc.cancer.gov/files/4bca7e32-7856-4e7c-bd26-e5753595f188

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 22; copy number 1: 2,589; copy number 2: 33,714; copy number 3: 17,700; copy number 4: 3,079; copy number 5: 673; copy number 6: 108; copy number 7: 836; copy number 8: 108; copy number 9: 42; copy number 12: 17; copy number 13: 20.

Homozygous deletions (total copy number 0; autosomes only): 22 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:75,384,059–75,590,649, 11 genes: AC139453.2, LSP1P2, AC139453.1, ALG1L6P, FAM86DP, LINC02018, ENPP7P2, SNRPCP10, AC133041.1, RPS3AP15, AC108724.1.
- chr7:102,579,104–102,679,295, 6 genes (within-gene range 0–2): AC105052.4, AC105052.1, UPK3BL1, AC105052.3, SPDYE2B, POLR2J2.
- chr9:64,369,394–64,466,498, 5 genes: ANKRD20A4P, RNU6-1193P, SNX18P9, CR769776.2, CYP4F25P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,804 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:111,353,275–113,901,237, 67 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr8:46,028,804–64,369,176, 258 genes, copy number 5–13 (within-gene range 4–13) (broad region; genes not listed).
- chr12:66,767–34,249,958, 831 genes, copy number 6–7 (broad region; genes not listed).
- chr17:73,163,035–77,281,897, 185 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr17:77,722,872–80,966,371, 93 genes, copy number 5–7 (within-gene range 1–7) (broad region; genes not listed).
- chr21:13,038,160–33,931,607, 370 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,077. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
